Somatic mutation profile of tumor specimen TCGA-D1-A17B-01A (aliquot TCGA-D1-A17B-01A-22D-A12J-09) from TCGA case TCGA-D1-A17B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.8 years (25,504 days).
Specimen TCGA-D1-A17B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695cd708-4a9e-452d-a545-7e4d116501d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17B-10A (Blood Derived Normal), aliquot TCGA-D1-A17B-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/901355c2-8c80-45cd-b093-f26bdeab53ab

The open-access MAF lists 340 somatic variants for this specimen: 269 protein-altering or splice-affecting, 65 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 65, Frame Shift Del 50, Nonsense Mutation 13, In Frame Del 10, Frame Shift Ins 7, 3'UTR 3, Splice Region 3, Splice Site 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1GALT1C1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 33/185 reads (18%) | catalogued as rs137853598, COSV58974430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767019228, COSV54204048; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as rs139016696, CM1310362, COSV57463432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.48T>G p.Y16* | Nonsense Mutation (SNP) | VAF 84/267 reads (31%) | hotspot (GDC flag); catalogued as rs587782187, CM110154, COSV64288363, COSV64293151, COSV64295030; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7292G>A p.R2431Q (on ENST00000614293; = p.R2401Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs770221339, COSV55803190; called by muse, mutect2, varscan2
- ABCG4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746516183, COSV100266676, COSV56644190; called by muse, mutect2, varscan2
- ACLY | c.867C>T p.S289= | Splice Region (SNP) | VAF 36/181 reads (20%) | catalogued as rs1281001958, COSV61251349; called by muse, mutect2, varscan2
- ACSM5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs765574822, COSV59372830; called by muse, mutect2, varscan2
- ACTRT2 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs780703424, COSV65759683; called by muse, mutect2, varscan2
- ADAMTS16 | c.2904C>A p.S968R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV56995247; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1183120397, COSV55002060; called by muse, mutect2, varscan2
- ADRB3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.86); catalogued as COSV61461673; called by muse, mutect2, varscan2
- AGAP3 | c.623G>A p.R208Q (on ENST00000622464; = p.R244Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1474456066, COSV58995114; called by muse, mutect2, varscan2
- ANKRD26 | c.2435T>A p.I812N | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV65776419; called by muse, mutect2, varscan2
- ANKRD52 | c.341C>A p.A114D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57285398; called by muse, mutect2
- ANO1 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs746634159, COSV62447275; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- ARHGAP17 | c.2159C>T p.T720M (on ENST00000289968 / NM_001006634.3; = p.T642M on NM_018054.6) | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as rs775712903, COSV51509168; called by muse, mutect2, varscan2
- ARHGAP31 | c.3062A>G p.N1021S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51795358; called by muse, mutect2, varscan2
- ARMH3 | c.1450_1452del p.K484del | In Frame Del (DEL) | VAF 23/131 reads (18%) | catalogued as rs748975345; called by pindel, varscan2
- ARSK | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as rs199509272, COSV66169451; called by muse, mutect2, varscan2
- ARVCF | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1480376529, COSV54267868; called by muse, mutect2, varscan2
- ATP1A3 | c.1033G>A p.V345M (on ENST00000545399 / NM_001256214.2; = p.V332M on NM_152296.5) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57488813; called by muse, mutect2
- ATP8B4 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as rs775878069, COSV52718501; called by muse, mutect2, varscan2
- BANK1 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 46/277 reads (17%) | catalogued as COSV59845450; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C1orf131 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs762716272, COSV59642582; called by muse, mutect2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C3orf84 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs562603081, COSV60412162; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs747591930; called by mutect2, varscan2
- CABS1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs758926757, COSV56733074; called by muse, mutect2, varscan2
- CCDC178 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV55781279; called by muse, mutect2
- CCDC6 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV54057639; called by muse, mutect2, varscan2
- CD209 | c.772T>C p.W258R | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs999202814, COSV52655421; called by muse, mutect2, varscan2
- CD6 | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV57840094; called by muse, mutect2, varscan2
- CD68 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770159428, COSV51511288; called by muse, mutect2, varscan2
- CDA | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV66751976; called by muse, mutect2, varscan2
- CDC14A | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60559888; called by muse, mutect2
- CES3 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV57594166; called by muse, mutect2, varscan2
- CFAP54 | c.7686A>G p.G2562= | Splice Region (SNP) | VAF 12/164 reads (7%) | catalogued as rs1010622110, COSV61572988; called by muse, mutect2
- CHIT1 | c.112del p.E38Rfs*24 | Frame Shift Del (DEL) | VAF 40/338 reads (12%) | catalogued as COSV55145321; called by mutect2, pindel, varscan2
- CHMP3 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as COSV55686768; called by muse, mutect2, varscan2
- CKAP5 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs773132498, COSV56363574; called by muse, mutect2, varscan2
- CLDN9 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs554337745, COSV60911107; called by muse, mutect2, varscan2
- COL16A1 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs777072840, COSV54701337; called by muse, mutect2, varscan2
- COL5A1 | c.3905del p.P1302Rfs*186 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs1564477140; called by mutect2, varscan2
- COL6A2 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs140643748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.5297G>A p.R1766Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as rs867057566, COSV62029257; called by muse, mutect2, varscan2
- COL7A1 | c.3317T>G p.F1106C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV60397456; called by muse, mutect2, varscan2
- COLGALT2 | c.573del p.M192Cfs*49 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | catalogued as COSV62729234; called by mutect2, pindel, varscan2
- COMP | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55875334; called by muse, mutect2, varscan2
- COPB1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs893380262, COSV51446948; called by muse, mutect2, varscan2
- CYP3A7 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748017013, COSV60480698, COSV60482109; called by muse, mutect2, varscan2
- DCAF4L2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs747761232, COSV60479886; called by muse, mutect2, varscan2
- DCLK1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55178361; called by muse, mutect2, varscan2
- DCT | c.555del p.F185Lfs*14 | Frame Shift Del (DEL) | VAF 14/143 reads (10%) | catalogued as rs762895555; called by mutect2, pindel
- DDX21 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV62555940; called by muse, mutect2, varscan2
- DDX31 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV60136940; called by muse, mutect2, varscan2
- DHX32 | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV52941342; called by muse, mutect2, varscan2
- DIP2C | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767505424, COSV55164855; called by muse, mutect2, varscan2
- DNAH2 | c.13085C>T p.T4362M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1281743012, COSV66721644; called by muse, mutect2, varscan2
- DOCK6 | c.5238C>T p.R1746= | Splice Region (SNP) | VAF 11/64 reads (17%) | catalogued as rs375809503; called by muse, mutect2, varscan2
- DTX2 | c.740A>T p.Y247F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV56862279; called by muse, mutect2
- DTX4 | c.1527dup p.G510Rfs*66 | Frame Shift Ins (INS) | VAF 15/93 reads (16%) | catalogued as rs762133243; called by mutect2, varscan2
- EDEM3 | c.1974del p.F658Lfs*4 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | catalogued as rs1173052284; called by mutect2, varscan2
- EFTUD2 | c.2856C>A p.F952L | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53655924; called by muse, mutect2, varscan2
- EMC1 | c.946T>C p.F316L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.6); catalogued as COSV61887022; called by muse, mutect2
- EML5 | c.5627_5629del p.G1876del (on ENST00000380664; = p.G1884del on NM_183387.3) | In Frame Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs760455698; called by pindel, varscan2
- EMSY | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV58262736; called by muse, mutect2, varscan2
- FAM222A | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV62723574; called by muse, mutect2, varscan2
- FAM234B | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs761686462, COSV52195532; called by muse, mutect2, varscan2
- FAM78B | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.325); catalogued as rs771748940, COSV57977890; called by muse, mutect2, varscan2
- FBN3 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as COSV54464702; called by muse, mutect2, varscan2
- FBXL19 | c.1558T>C p.W520R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV57943476; called by muse, mutect2, varscan2
- FCRL3 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV63842911; called by muse, mutect2, varscan2
- FMR1 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | catalogued as rs782514882, COSV54425198; called by muse, mutect2
- FMR1 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.855); catalogued as rs781858260, COSV54425285; called by muse, varscan2
- FOXP1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59546112; called by muse, mutect2, varscan2
- FRMD6 | c.466G>A p.A156T (on ENST00000344768 / NM_001267046.2; = p.A148T on NM_152330.4) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as COSV61089182; called by muse, mutect2, varscan2
- FRYL | c.1645del p.E549Kfs*19 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as COSV51962239; called by mutect2, pindel, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- GAB3 | c.1707G>T p.Q569H | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65820020; called by muse, mutect2, varscan2
- GABRB2 | c.1408C>T p.R470C (on ENST00000274547; = p.R432C on NM_000813.3) | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774391847, COSV50905801; called by muse, mutect2, varscan2
- GK2 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV62627497; called by muse, mutect2, varscan2
- GLUD2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60152286; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs749150409; called by mutect2, varscan2
- GPR158 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs146528842; called by muse, mutect2, varscan2
- GPRASP1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV64355469, COSV64355947; called by muse, mutect2, varscan2
- GSX2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs1350092216, COSV58843167; called by muse, mutect2, varscan2
- GTF2H3 | c.272T>G p.F91C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1303260362, COSV57459271; called by muse, mutect2, varscan2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 20/87 reads (23%) | catalogued as rs745885335; called by mutect2, varscan2
- H2AZ1 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56455540; called by muse, mutect2, varscan2
- HCFC1 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782310209, COSV60074207; called by muse, mutect2, varscan2
- HEATR5A | c.3312A>T p.E1104D | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66342659; called by muse, mutect2, varscan2
- HECTD1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs1175145295, COSV67947368; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HMCN1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs779304400, COSV54913266; called by muse, mutect2, varscan2
- HRC | c.1144_1146del p.E382del | In Frame Del (DEL) | VAF 25/199 reads (13%) | catalogued as rs763817475; called by pindel, varscan2
- HSD3B7 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs560826820, COSV52680927; called by muse, mutect2, varscan2
- HSPBP1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs368514742; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs759151580; called by mutect2, varscan2
- IFNA14 | c.550dup p.R184Kfs*15 | Frame Shift Ins (INS) | VAF 18/194 reads (9%) | catalogued as rs780337693; called by mutect2, pindel
- IFT122 | c.3698G>A p.R1233H (on ENST00000348417 / NM_052989.3; = p.R1174H on NM_018262.4) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs201755623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHA2 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs369079295; called by muse, mutect2, varscan2
- IHH | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV55393507; called by muse, mutect2
- INPP4A | c.2377C>T p.R793* (on ENST00000074304 / NM_001134224.1; = p.R754* on NM_001566.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV50790458; called by muse, mutect2, varscan2
- ITLN2 | c.178T>C p.C60R | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.454); catalogued as COSV63537926; called by muse, mutect2
- JAZF1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52238088; called by muse, mutect2, varscan2
- KCNA6 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs946789647, COSV54973785; called by muse, mutect2, varscan2
- KCNJ10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs769464065, COSV63634142; called by muse, mutect2, varscan2
- KCNJ14 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53519449; called by muse, mutect2, varscan2
- KCNK6 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV54579919; called by muse, mutect2
- KLF15 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56180389; called by muse, mutect2, varscan2
- KLHL15 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV60140748; called by muse, mutect2, varscan2
- KRT81 | c.1161G>T p.R387S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV59810470; called by muse, mutect2, varscan2
- KRTCAP2 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768462233, COSV55279400; called by muse, mutect2, varscan2
- LARS1 | c.2867G>A p.R956H (on ENST00000394434 / NM_020117.11; = p.R929H on NM_016460.3) | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs777240648, COSV50973713; called by muse, mutect2, varscan2
- LGALS3BP | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53165367; called by muse, mutect2, varscan2
- LGALS4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760505571, COSV57044049; called by muse, mutect2, varscan2
- LRP2 | c.11662C>T p.R3888C | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750352540, COSV55560019; called by muse, mutect2, varscan2
- MACROH2A2 | c.438dup p.K147Efs*21 | Frame Shift Ins (INS) | VAF 14/90 reads (16%) | catalogued as rs775088830; called by mutect2, varscan2
- MAN2B1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757860525, COSV54418564; called by muse, mutect2, varscan2
- MAP3K13 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV53988138; called by muse, mutect2
- MAPK7 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs371955456; called by muse, varscan2
- MAPRE2 | c.32A>T p.N11I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55819858; called by muse, varscan2
- MAS1 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758684185, COSV53121533; called by muse, mutect2, varscan2
- MC1R | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV59625878; called by muse, mutect2, varscan2
- MCHR1 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV50761745; called by muse, mutect2, varscan2
- MEGF6 | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53891701; called by muse, mutect2, varscan2
- MEIS2 | c.86C>T p.A29V (on ENST00000561208 / NM_170675.5; = p.A16V on NM_002399.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as rs772370515, COSV54939015; called by muse, mutect2
- MELTF | c.1822del p.R608Efs*20 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as COSV56381413; called by pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs545655356, COSV61790961; called by muse, varscan2
- MKS1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 15/189 reads (8%) | catalogued as COSV56597193; called by muse, mutect2
- MMRN2 | c.1375_1377del p.E459del | In Frame Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs756368217; called by pindel, varscan2
- MRGPRF | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.142); catalogued as rs1432353088, COSV57996143; called by muse, mutect2, varscan2
- MRPS12 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1225449479, COSV55500282; called by muse, mutect2, varscan2
- MRPS18C | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs375755956; called by muse, mutect2, varscan2
- MTCL1 | c.4402C>T p.P1468S (on ENST00000306329 / NM_001378206.1; = p.P1149S on NM_015210.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV60407840; called by muse, mutect2
- MTRR | c.1991C>T p.A664V (on ENST00000264668; = p.A637V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs764159535, COSV52944924; called by muse, mutect2, varscan2
- NAV2 | c.6553G>A p.G2185R (on ENST00000396087 / NM_001244963.2; = p.G2126R on NM_145117.5) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as rs767241462, COSV60661124; called by muse, mutect2, varscan2
- NBEAL2 | c.2773A>G p.T925A | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV52759993; called by muse, mutect2, varscan2
- NBEAL2 | c.6166del p.Q2056Rfs*24 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs780892300; called by mutect2, pindel, varscan2
- NEIL1 | c.753_755del p.E251del | In Frame Del (DEL) | VAF 32/180 reads (18%) | catalogued as rs770433190; called by pindel, varscan2
- NEK10 | c.1832del p.P611Rfs*9 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as COSV58281740; called by mutect2, pindel, varscan2
- NES | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs1356462487, COSV63961535; called by muse, mutect2, varscan2
- NID1 | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51623120, COSV51624260; called by muse, mutect2, varscan2
- NOTCH3 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54636128; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NPRL2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375459962; called by muse, mutect2, varscan2
- OR51S1 | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV59059009; called by muse, mutect2, varscan2
- OSBP2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs759516921, COSV60244702; called by muse, mutect2, varscan2
- PADI3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs377687938; called by muse, mutect2, varscan2
- PCDHA5 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.483); catalogued as rs999470777, COSV65349874, COSV65353767, COSV65355774; called by muse, mutect2, varscan2
- PCDHA6 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); catalogued as rs782217006, COSV65345170; called by muse, varscan2
- PDE6H | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs752057504, COSV56760652; called by muse, mutect2
- PICK1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746669587, COSV57634949; called by muse, mutect2, varscan2
- PIP5K1C | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58953713; called by muse, mutect2, varscan2
- PKD1 | c.4610A>G p.E1537G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV51919408; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 35/222 reads (16%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLXNA1 | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1184304062, COSV52528548; called by muse, varscan2
- POLR3B | c.1628-1G>T p.X543_splice | Splice Site (SNP) | VAF 6/129 reads (5%) | catalogued as COSV57280946; called by muse, mutect2
- POU2F1 | c.1439C>T p.P480L (on ENST00000541643 / NM_001365848.1; = p.P503L on NM_002697.4) | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV54819632; called by muse, mutect2, varscan2
- PRDM1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV64845711; called by muse, mutect2, varscan2
- PRRX1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770288919, COSV53410645; called by muse, mutect2, varscan2
- PRUNE2 | c.1504G>C p.A502P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1170419934, COSV65043318; called by muse, mutect2
- PSD | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs144736600; called by muse, mutect2, varscan2
- PTCH1 | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs376084632, COSV59481097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- PUS1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs755448329, COSV59035847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDNL | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62485418; called by muse, mutect2, varscan2
- RAB4B | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1159610126, COSV63825340; called by muse, mutect2
- RALGAPB | c.268T>G p.Y90D | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53439948; called by muse, mutect2, varscan2
- RBM45 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV53721438; called by muse, mutect2, varscan2
- RECQL5 | c.2109G>T p.E703D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58642559; called by muse, mutect2
- RET | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV60699639; called by muse, mutect2, varscan2
- RGL2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV69916292; called by muse, mutect2, varscan2
- RNH1 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV62251249; called by muse, mutect2, varscan2
- RPS6KB2 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs199570304, COSV57051665, COSV57055570; called by muse, mutect2, varscan2
- RYR2 | c.6519G>T p.E2173D | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs368920731, COSV63694251; called by muse, mutect2
- SEMA3D | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV52397182; called by muse, mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 26/141 reads (18%) | catalogued as rs759211171; called by mutect2, varscan2
- SH3RF1 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52922285; called by muse, mutect2
- SHANK1 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs565118421, COSV53254434; called by muse, mutect2, varscan2
- SIAE | c.1308_1310del p.N436del | In Frame Del (DEL) | VAF 42/326 reads (13%) | catalogued as rs752182375; called by pindel, varscan2
- SIGLEC9 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs755507123, COSV51584041; called by muse, mutect2, varscan2
- SLC13A1 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013391; called by muse, mutect2
- SLC16A2 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV52085875; called by muse, mutect2, varscan2
- SLC52A3 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs374661714; called by muse, mutect2, varscan2
- SLC6A3 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54365860; called by muse, mutect2, varscan2
- SLC6A5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1383470600, COSV54228600; called by muse, mutect2, varscan2
- SLC8A1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV60475001; called by muse, mutect2
- SMARCA5 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV51645500, COSV51646412; called by muse, mutect2
- SMOX | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV53865886, COSV99603440; called by muse, mutect2
- SNW1 | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.537); catalogued as COSV55055073; called by muse, mutect2, varscan2
- SNX6 | c.799T>G p.L267V (on ENST00000652385; = p.L139V on NM_021249.5) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV61919134; called by muse, mutect2, varscan2
- SPEN | c.4892T>G p.L1631R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV65363852; called by muse, mutect2
- SPEN | c.10427C>T p.T3476I | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65270516; called by muse, mutect2, varscan2
- SRRM2 | c.7300G>A p.A2434T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV51941113; called by muse, mutect2
- STAM | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66325560; called by muse, mutect2, varscan2
- STRBP | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.062); catalogued as rs750032338, COSV62118881; called by muse, mutect2, varscan2
- STXBP2 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs542557411, COSV55401886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULT1C3 | c.41del p.K14Sfs*10 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | catalogued as rs770034585; called by mutect2, pindel, varscan2
- SYNE2 | c.15324G>T p.M5108I | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV59955109, COSV59956326; called by muse, mutect2, varscan2
- TARS2 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as rs775749716, COSV64695957; called by muse, mutect2, varscan2
- TFAP2C | c.1241A>C p.N414T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV52372010; called by muse, mutect2, varscan2
- TFIP11 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs763900688, COSV53226693; called by muse, mutect2, varscan2
- TGFB3 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53170365; called by muse, varscan2
- THAP8 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as COSV53078498; called by muse, mutect2, varscan2
- THOC2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as COSV55549430; called by muse, mutect2, varscan2
- TIAM1 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754307192, COSV54556810; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 32/151 reads (21%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM170A | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs376793219; called by muse, mutect2, varscan2
- TMEM236 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1016859711; called by muse, mutect2, varscan2
- TMEM74 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1214097082, COSV52463605; called by muse, mutect2, varscan2
- TNRC6C | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs978647209, COSV56948343; called by muse, mutect2, varscan2
- TNS4 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV54186033; called by muse, mutect2, varscan2
- TOX | c.1469T>C p.M490T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.775); catalogued as rs1473131387, COSV63847735; called by muse, mutect2, varscan2
- TRIM71 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs982336353, COSV101070479, COSV67470139; called by muse, mutect2, varscan2
- TRO | c.3748G>A p.G1250S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.181); catalogued as rs749370071, COSV51503487, COSV99435857; called by muse, mutect2, varscan2
- TRPM4 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs138718906, COSV53264912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC14 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as rs753896523, COSV56010120; called by muse, mutect2, varscan2
- TTI2 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62452059; called by muse, mutect2, varscan2
- TUBA8 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1270367236, COSV57813360; called by muse, mutect2, varscan2
- TULP4 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1479558820, COSV65577385; called by muse, mutect2, varscan2
- UNC5B | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs551142023, COSV58978261; called by muse, mutect2, varscan2
- USP22 | c.1100G>C p.R367P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV54947385; called by mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 40/215 reads (19%) | catalogued as rs761528888; called by mutect2, varscan2
- UTP20 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs765182802, COSV55379798; called by muse, mutect2, varscan2
- VPS33A | c.1376del p.G459Afs*86 | Frame Shift Del (DEL) | VAF 56/327 reads (17%) | catalogued as rs1357715083, COSV57357082; called by mutect2, pindel, varscan2
- ZBTB7C | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as COSV59689556; called by muse, mutect2, varscan2
- ZC3H18 | c.2042+1G>A p.X681_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV56325877; called by muse, mutect2, varscan2
- ZFR2 | c.1467del p.R490Gfs*11 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs1361833554; called by mutect2, pindel, varscan2
- ZNF233 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs150005688; called by muse, mutect2, varscan2
- ZNF292 | c.2278G>T p.G760C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV60541675; called by muse, mutect2, varscan2
- ZNF488 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs781991498; called by muse, mutect2, varscan2
- ZNF665 | c.1406C>T p.T469I (on ENST00000600412; = p.T534I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs376555296; called by muse, mutect2, varscan2
- ZYX | c.772T>G p.S258A | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59556823; called by muse, mutect2, varscan2
- ANKRD27 | c.839del p.P280Hfs*23 | Frame Shift Del (DEL) | VAF 36/285 reads (13%) | called by mutect2, pindel, varscan2
- ANLN | c.2695del p.T899Hfs*16 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- CHD8 | c.5713del p.L1905Ffs*30 (on ENST00000646647 / NM_001170629.2; = p.L1626Ffs*30 on NM_020920.4) | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- CIC | c.436_437del p.S146* | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- CTNNBL1 | c.172dup p.R58Kfs*7 | Frame Shift Ins (INS) | VAF 24/155 reads (15%) | called by mutect2, varscan2
- CUL2 | c.1756_1758del p.L586del | In Frame Del (DEL) | VAF 28/242 reads (12%) | called by pindel, varscan2
- DDX46 | c.590del p.K197Sfs*4 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- DTX4 | c.1080del p.V361Sfs*6 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- EPB41 | c.621_622del p.H207Qfs*12 | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | called by pindel, varscan2
- FBXO38 | c.2090del p.N697Tfs*32 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, varscan2
- HIVEP1 | c.7839del p.V2614Ffs*2 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | called by mutect2, pindel, varscan2
- KMT2B | c.1778_1784dup p.L596Sfs*5 | Frame Shift Ins (INS) | VAF 24/157 reads (15%) | called by mutect2, pindel, varscan2
- KRTAP5-1 | c.287del p.K96Rfs*? | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- LARP4 | c.1952del p.N651Mfs*33 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- MX2 | c.608del p.G203Afs*19 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- NCOR2 | c.1497_1498del p.Q500Afs*22 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by muse*, mutect2, varscan2*
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 37/259 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1732_1733del p.D578Pfs*23 (on ENST00000521381 / NM_181523.3; = p.D308Pfs*23 on NM_181504.4) | Frame Shift Del (DEL) | VAF 32/239 reads (13%) | called by pindel, varscan2
- PIK3R2 | c.1000del p.D334Tfs*7 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- PRDM8 | c.1949del p.K650Rfs*9 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- RSPH9 | c.778_780del p.Y260del | In Frame Del (DEL) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- SEMA3E | c.2026_2028del p.E676del | In Frame Del (DEL) | VAF 30/176 reads (17%) | called by pindel, varscan2
- SEPTIN4 | c.495_497del p.K165del | In Frame Del (DEL) | VAF 20/146 reads (14%) | called by pindel, varscan2
- SLCO4A1 | c.1755_1758del p.F585Lfs*2 | Frame Shift Del (DEL) | VAF 35/241 reads (15%) | called by mutect2, pindel, varscan2
- STAT6 | c.841del p.Q281Rfs*3 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- TCTN2 | c.721del p.A242Pfs*45 | Frame Shift Del (DEL) | VAF 26/159 reads (16%) | called by mutect2, pindel, varscan2
- TUBG1 | c.44_47del p.N15Rfs*58 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- UBE2E3 | c.155_156del p.S52* | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | called by pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 34/189 reads (18%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.1039del p.I347Sfs*51 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- ZNF148 | c.266dup p.N89Kfs*2 | Frame Shift Ins (INS) | VAF 68/410 reads (17%) | called by mutect2, pindel, varscan2
- AGPAT2 | c.561C>T p.G187= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs756686507, COSV58248064; called by muse, mutect2, varscan2
- AJUBA | c.1611T>C p.Y537= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV52985759; called by muse, mutect2, varscan2
- ATF5 | c.768C>T p.S256= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs143295930, COSV100352031; called by muse, mutect2, varscan2
- C3orf20 | c.633C>T p.L211= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs200768036, COSV53786570; called by muse, mutect2, varscan2
- CDH12 | c.1161G>A p.P387= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs553702042, COSV66388713; called by muse, mutect2, varscan2
- CFAP46 | c.5613G>A p.A1871= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs779626189, COSV54154502; called by muse, mutect2, varscan2
- CMTM1 | c.495G>A p.P165= (on ENST00000457188 / NM_181269.3; = p.P282= on NM_052999.4) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs756037366, COSV51749055; called by muse, mutect2
- COL11A1 | c.1818G>A p.P606= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs748195901, COSV62187907; called by mutect2, varscan2
- COL4A3 | c.3945A>G p.P1315= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as rs189574905; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CYP4V2 | c.1308C>T p.P436= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs139324591; called by muse, mutect2, varscan2
- DTX2 | c.375A>G p.E125= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV56862265; called by muse, mutect2, varscan2
- DUSP12 | c.204G>T p.A68= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs749222428, COSV63411497; called by muse, mutect2, varscan2
- EP400 | c.7068C>T p.I2356= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs765442346, COSV57770007; called by muse, mutect2, varscan2
- GABRA5 | c.1293C>T p.I431= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs776674172, COSV59479043, COSV59479784; called by muse, mutect2
- GAS6 | c.2016C>T p.P672= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs77167214, COSV59852254; called by muse, mutect2, varscan2
- GJA10 | c.729T>C p.Y243= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs145965891; called by muse, mutect2, varscan2
- GPD1 | c.687G>A p.R229= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV56548505; called by muse, mutect2, varscan2
- GPSM1 | c.1767C>T p.H589= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs782156042, COSV52517878; called by muse, mutect2, varscan2
- GRM3 | c.1206C>T p.H402= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs1467173545, COSV64474545; called by muse, mutect2, varscan2
- GSX2 | c.27G>A p.S9= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1459962469, COSV58843160; called by muse, mutect2, varscan2
- HSPA1L | c.1437G>A p.T479= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs532485515, COSV65148795, COSV65149196; called by muse, mutect2, varscan2
- HTR1A | c.1191C>T p.P397= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs748931273, COSV60501515; called by muse, mutect2, varscan2
- HTR1B | c.36G>A p.P12= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV64051630; called by muse, mutect2, varscan2
- ITSN1 | c.3219A>G p.G1073= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs1327533622, COSV66081680; called by muse, mutect2, varscan2
- JAK1 | c.2919C>T p.N973= | Silent (SNP) | VAF 25/228 reads (11%) | catalogued as COSV61093138; called by muse, mutect2, varscan2
- KIAA2026 | c.2769G>A p.P923= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs367658582; called by muse, mutect2, varscan2
- KLHDC8A | c.570C>T p.N190= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs111740439; called by muse, mutect2, varscan2
- LMBR1 | c.210G>A p.V70= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV62221284; called by muse, mutect2, varscan2
- LRCH2 | c.120C>T p.G40= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57753667; called by muse, mutect2, varscan2
- LRRC1 | c.510T>A p.L170= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63829731; called by muse, varscan2
- MINK1 | c.366C>A p.G122= | Silent (SNP) | VAF 48/270 reads (18%) | catalogued as COSV61790948; called by muse, varscan2
- MPEG1 | c.1740C>T p.S580= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs186140164, COSV57092154; called by muse, mutect2, varscan2
- MYBPC3 | c.1815C>T p.D605= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs768380030, COSV57029575; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH11 | c.3492T>C p.T1164= | Silent (SNP) | VAF 55/272 reads (20%) | catalogued as COSV55558551; called by muse, mutect2, varscan2
- MYO5B | c.3753C>T p.H1251= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs548510364, COSV53222692; called by muse, mutect2, varscan2
- NAPA | c.603C>T p.S201= | Silent (SNP) | VAF 48/295 reads (16%) | catalogued as rs759871131, COSV54550696; called by muse, mutect2, varscan2
- NBEAL2 | c.6162C>T p.S2054= | Silent (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- NKG7 | c.168C>T p.H56= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs765331087, COSV52467712; called by muse, mutect2
- NPTN | c.828C>T p.N276= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs771730924, COSV54738180; called by muse, mutect2, varscan2
- OR1C1 | c.513C>T p.S171= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV68715926; called by muse, mutect2, varscan2
- PDE3B | c.2581C>T p.L861= | Silent (SNP) | VAF 13/322 reads (4%) | catalogued as COSV56386124; called by muse, mutect2
- PEX5L | c.1071T>C p.P357= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV55849317; called by muse, mutect2, varscan2
- PIK3CD | c.1083G>A p.S361= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs1001849803, COSV63129675; called by muse, mutect2, varscan2
- PIK3R5 | c.1347G>A p.T449= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs778905637, COSV52655464; called by muse, mutect2, varscan2
- PLCD1 | c.531C>T p.D177= | Silent (SNP) | VAF 47/303 reads (16%) | catalogued as rs368360654; called by muse, mutect2, varscan2
- POLR1A | c.843G>A p.S281= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs1419807566, COSV55695179; called by muse, mutect2, varscan2
- PPFIA3 | c.1326C>T p.N442= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV61950435; called by muse, mutect2, varscan2
- PRAMEF20 | c.462C>T p.C154= | Silent (SNP) | VAF 29/378 reads (8%) | called by muse, mutect2
- PSMD14 | c.36T>C p.P12= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV68833060; called by muse, mutect2, varscan2
- PXDC1 | c.327G>A p.T109= | Silent (SNP) | VAF 59/310 reads (19%) | catalogued as rs755320106, COSV100977186, COSV66661728; called by muse, mutect2, varscan2
- RBM10 | c.990C>T p.N330= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1431043548, COSV61310030; called by muse, mutect2, varscan2
- SLC9A4 | c.570C>T p.D190= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs755300636, COSV54835828; called by muse, mutect2, varscan2
- TACC2 | c.75C>T p.P25= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs774154821, COSV57760927; called by muse, mutect2, varscan2
- TBL3 | c.864G>A p.P288= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs367676223; called by muse, mutect2, varscan2
- TC2N | c.942G>A p.Q314= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV61747487; called by muse, mutect2, varscan2
- TGFB3 | c.276C>A p.T92= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as rs774368444, COSV53170353; called by muse, varscan2
- TLN1 | c.5139T>C p.I1713= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV59208960; called by muse, mutect2, varscan2
- TRIM10 | c.213C>A p.P71= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as COSV64989861, COSV64989869; called by muse, mutect2, varscan2
- TSKS | c.714G>A p.R238= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV55876310; called by muse, mutect2, varscan2
- TTN | c.82326C>T p.V27442= (on ENST00000591111; = p.V20018= on NM_003319.4) | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV60158209; called by muse, mutect2, varscan2
- UQCRFS1 | c.714C>T p.C238= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV59185077; called by muse, mutect2, varscan2
- USP19 | c.1929G>T p.V643= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV60046784; called by muse, mutect2, varscan2
- ZBTB34 | c.741C>T p.S247= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs201410093, COSV59860174; called by muse, mutect2, varscan2
- ZCCHC14 | c.516C>T p.H172= (on ENST00000268616; = p.H309= on NM_015144.3) | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs775745758, COSV51887660; called by muse, varscan2
- ZNF285 | c.147C>T p.D49= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs775117926, COSV58409224; called by muse, mutect2, varscan2
- ANKMY1 | c.-88_-86del | 5'UTR (DEL) | VAF 17/119 reads (14%) | called by pindel, varscan2
- DGKD | c.*2C>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99895681; called by muse, mutect2, varscan2
- ELOB | c.*406C>T | 3'UTR (SNP) | VAF 15/172 reads (9%) | catalogued as rs752101364, COSV99241301; called by muse, mutect2
- GPATCH2L | c.1053-60T>G | Intron (SNP) | VAF 58/302 reads (19%) | catalogued as COSV55049318; called by muse, mutect2, varscan2
- PRPS2 | c.306+9G>T | Intron (SNP) | VAF 19/106 reads (18%) | catalogued as COSV66126382; called by muse, mutect2, varscan2
- RUBCN | c.*446C>T | 3'UTR (SNP) | VAF 23/165 reads (14%) | catalogued as rs541997965, COSV56368446; called by muse, mutect2, varscan2
